Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1Y1, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1Y1-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination (cito)

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – left breast and axillary tissues

Unit in charge:

Physician in charge:

ref. No.

Material collected on:

Material received on:

Expected time of examination: 5 working days

Clinical diagnosis:

ICD-0-3

carcinoma, infiltrating duct, NOS 8500/3

Site: breast, NOS C50.9 for 4/12/11

Examination performed on:

Macroscopic description:

Left breast, sized 22 x 18 x 9 cm, removed with axillary tissues sized 10 x 11 x 5 cm and with a skin flap of 23 x 19 cm. Nipple retracted, skin resembling orange peel.

Tumour sized 6.0 x 6.0 x 3.5 found on the border of upper quadrants, located 3.0 cm from the upper boundary, 1.5 cm from the base and 0 cm from the skin.

Lymph nodes 1.8 cm in length.

Microscopic description:

Carcinoma ductale invasivum - NHG3 (3 + 2 + 3 / 35 mitoses/10 HPF - visual area 0.55 mm).

Mamilla sine laesionibus.

Glandular tissue showing lesions of the type mastopathia fibrosa et cystica.

AXILLARY LYMPH NODES:

Metastases carcinomatosae in lymphonodo (No I/XXI).

Infiltratio capsulae lymphonodi et telae perinodalis.

Histopathological diagnosis:

Carcinoma ductale invasivum mammae sinistrae. Invasive ductal carcinoma of the left breast.

Metastases carcinomatosae in lymphonodo (No I/XXI) (NHG3, pT3, pN1a). Cancer metastases in the lymph nodes (No I/XXI)

[page 2 of 2]
Results of immunohistochemical examination:

Estrogen receptors found in 10-75% of neoplastic cell nuclei. Progesterone receptors found in over 75% of neoplastic cell nuclei. HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) rabbit antibody. Negative reaction in invasive cancerous cells (Score=3+).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 02cf0b0c-78e8-4c3d-b476-580dd616df98 (TCGA-D8-A1Y1.1B198706-8844-452A-8F5B-8880A239717C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).